MMRF case MMRF_1164 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/56765ee0-fa94-4758-b118-6cf940e90c16

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 372 days (1.0 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.2 years (25,632 days); ISS stage: III; Days to last known disease status: 372 days (1.0 years); Days to last follow up: 372 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 372 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 280 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 280 days; Days to treatment end: 372 days (1.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 372.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 10.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 50.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 20 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 9.6 µg/mL; Lactate Dehydrogenase 4.08 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 7.31 mg/dL.
- Day 95 (ECOG 0): M Protein 0.5 g/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 6.1 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 4.24 mmol/L.
- Day 175 (ECOG 0): Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.84 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 5.5 mmol/L.
- Day 266 (ECOG 0): M Protein 0.2 g/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.39 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day 1: Weight: 84 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1164_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1164_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
